Gene-level copy-number profile of tumor specimen TCGA-BA-5149-01A from TCGA case TCGA-BA-5149, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.0 years (17,177 days).
Specimen TCGA-BA-5149-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b3c0e96e-15e1-468f-80d6-e78854c58366.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-5149-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/720213da-abcd-4624-9725-867ac82e030b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,005; copy number 2: 15,246; copy number 3: 31,786; copy number 4: 6,834; copy number 5: 3,205; copy number 6: 97; copy number 7: 1,534; copy number 8: 40; copy number 26: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-5149-01A-01D-1510-01): tumor purity 0.5, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,634 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7 (broad region; genes not listed).
- chr11:68,891,276–72,080,693, 100 genes, copy number 8–26 (within-gene range 2–26) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 146. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
